TCGA case TCGA-CJ-4869 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/06d86d68-0fd5-4c6e-8783-ed732a3291e8

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 49.1 years (17,923 days); Year of diagnosis: 2004; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 10.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib Tosylate; Initial disease status: Recurrent Disease; Days to treatment start: 767 days (2.1 years); Days to treatment end: 854 days (2.3 years); Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib Malate; Initial disease status: Recurrent Disease; Days to treatment start: 881 days (2.4 years); Days to treatment end: 1,963 days (5.4 years); Route of administration: Oral.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 53.9 years (19,677 days); Days to diagnosis: 1,754 days (4.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (3 entries)
- Day 1,754 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 2,554 days (7.0 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Platelets: Normal.
- Leukocytes: Normal.
- Hemoglobin: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-4869-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 3; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-CJ-4869-01A-02-BS2: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 10.
  Slide TCGA-CJ-4869-01A-01-BS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 15.
- Sample TCGA-CJ-4869-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-4869-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 3.4; Intermediate dimension: 0.9; Shortest dimension: 0.9.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Nexavaar; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Sutent; Therapy regimen: Recurrence.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: At Recurrence/Progression Of Disease.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Subject Positive for Neo-Adjuvant Therapy.
- Neoadjuvant therapy: Prior malignancy and neo-adjuvant therapy per e-mail. (No data in OC.).
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,554 days; disease-specific survival: no event (censored), 2,554 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,754 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CJ-4869-01A-02D-1423-01): tumor purity 0.39, ploidy 1.91, whole-genome doublings 0.
